Gene-level copy-number profile of tumor specimen TARGET-10-PARHES-09A from TARGET case TARGET-10-PARHES, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,698 days).
Specimen TARGET-10-PARHES-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.bce9b6f0-bd46-5931-a042-ec5fb4b848df.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARHES-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/9ce08fe0-313c-4467-be29-3d8f011b690d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 2,473; copy number 2: 57,727; copy number 3: 13; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,311,808, 9 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr14:22,415,362–22,439,015, 4 genes: AC244502.3, TRDV2, TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
